Somatic mutation profile of tumor specimen 43e0432b-343d-4e12-817f-21281c (aliquot 43e0432b-343d-4e12-817f-21281c_D6_1) from CPTAC case 11CO048, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 43e0432b-343d-4e12-817f-21281c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6ee6a58-70dc-486c-8899-b2ab890f2fd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 474590db-eaf1-4d70-a4f7-81a026 (Blood Derived Normal), aliquot 474590db-eaf1-4d70-a4f7-81a026_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4322ae9-5e2f-416e-95a8-7ba043bdf217

The open-access MAF lists 209 somatic variants for this specimen: 125 protein-altering or splice-affecting, 50 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 50, Intron 13, Nonsense Mutation 10, RNA 6, 5'Flank 5, 3'UTR 4, 3'Flank 3, 5'UTR 3, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1A | c.2137G>A p.A713T | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs886037945, CM1314620, COSV64197352; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 55/179 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.272G>A p.W91* | Nonsense Mutation (SNP) | VAF 71/225 reads (32%) | hotspot (GDC flag); catalogued as COSV52734595, COSV53139118; called by muse, mutect2, varscan2
- A2M | c.4365G>A p.T1455= | Splice Region (SNP) | VAF 12/115 reads (10%) | catalogued as rs1247896058; called by muse, mutect2, varscan2
- AASS | c.1907T>C p.L636P | Missense Mutation (SNP) | VAF 12/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs961250435; called by muse, mutect2
- ABCA13 | c.14186G>A p.R4729H | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs372286953, COSV68943281; called by muse, mutect2, varscan2
- ABLIM3 | c.884T>C p.I295T | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs765150498; called by muse, mutect2, varscan2
- ACTR3B | c.1177G>T p.V393F | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.234); catalogued as COSV99754702; called by muse, mutect2, varscan2
- ADAMTS20 | c.3724G>C p.D1242H | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV101166183; called by muse, mutect2
- ANKS1A | c.2404G>A p.V802M | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774617212; called by muse, mutect2, varscan2
- B4GALNT4 | c.1873G>A p.V625M | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs1475258844, COSV57324589; called by muse, varscan2
- CACNG2 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 73/512 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as rs1169099240, COSV55633030; called by muse, mutect2, varscan2
- CLCNKA | c.1183C>T p.R395W | Missense Mutation (SNP) | VAF 121/427 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs574988239; called by muse, mutect2, varscan2
- CNTNAP4 | c.1928G>T p.R643I | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.66); catalogued as COSV100270266; called by muse, mutect2, varscan2
- COL4A5 | c.692A>C p.E231A | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.321); catalogued as COSV100087879; called by muse, mutect2
- DDHD2 | c.2080G>A p.V694I | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.044); catalogued as rs370808506; called by muse, mutect2, varscan2
- DNAAF3 | c.1238G>A p.R413Q (on ENST00000524407 / NM_001256715.2; = p.R460Q on NM_178837.4) | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.552); catalogued as rs771791101; called by muse, mutect2, varscan2
- DOCK4 | c.3704G>A p.R1235Q | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.087); catalogued as rs1284249260; called by muse, mutect2, varscan2
- ELAPOR1 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as rs757611417; called by muse, mutect2, varscan2
- EPHA6 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763947048, COSV67577491; called by muse, mutect2, varscan2
- EVL | c.244C>T p.R82* (on ENST00000402714 / NM_001330221.2; = p.R84* on NM_016337.3) | Nonsense Mutation (SNP) | VAF 13/92 reads (14%) | catalogued as rs1209498180, COSV67375671; called by muse, mutect2, varscan2
- FAM228B | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs549465815; called by muse, mutect2, varscan2
- FLCN | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs765251703, COSV53259612; called by muse, mutect2
- FRRS1L | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1446134179; called by muse, mutect2, varscan2
- GABRA3 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as rs754301642, COSV64795089; called by muse, mutect2, varscan2
- GALNT18 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751976870; called by muse, mutect2, varscan2
- GCFC2 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.076); catalogued as rs1189717390; called by muse, mutect2, varscan2
- GPR19 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs554350887, COSV60123076; called by muse, mutect2, varscan2
- GRIA1 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 117/452 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53592687; called by muse, mutect2, varscan2
- GUCY1A2 | c.2152G>T p.V718F | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99974897; called by muse, mutect2, varscan2
- HOXC6 | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 34/231 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.25); catalogued as rs778234830; called by muse, mutect2, varscan2
- HS3ST6 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as rs373745703; called by muse, mutect2
- HSD3B2 | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 121/460 reads (26%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs143634775; called by muse, mutect2, varscan2
- IGKV3D-20 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs1465992319; called by muse, mutect2, varscan2
- IKZF1 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 25/467 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1040607869, COSV58783153; called by muse, mutect2
- IRX2 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1415210624; called by muse, mutect2, varscan2
- ITIH4 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs995229568, COSV56573061, COSV56576209; called by muse, mutect2
- KMT2A | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 22/247 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.67); catalogued as rs374545538, COSV63293673; called by muse, mutect2
- KMT2C | c.3631C>T p.Q1211* | Nonsense Mutation (SNP) | VAF 30/348 reads (9%) | catalogued as COSV51434905; called by muse, mutect2
- MAGEB10 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV63310817; called by muse, mutect2
- MC5R | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 65/359 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs147915585; called by muse, mutect2, varscan2
- MMP16 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs772275333, COSV54173568, COSV54192724; called by muse, mutect2
- NAA40 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.686); catalogued as rs912117274; called by muse, mutect2, varscan2
- NCAPG2 | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as rs1292378389, COSV51984492; called by muse, mutect2, varscan2
- NFATC4 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 45/313 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs747668845, COSV51609189; called by muse, mutect2, varscan2
- NLGN4X | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 155/323 reads (48%) | catalogued as COSV52010465; called by muse, mutect2, varscan2
- NLRP10 | c.1837A>G p.K613E | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1268417555; called by muse, mutect2, varscan2
- OTOG | c.5849C>T p.T1950M | Missense Mutation (SNP) | VAF 71/420 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs758489218; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHGB2 | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as rs750073404; called by muse, varscan2
- PCNX1 | c.3194G>A p.R1065H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs373015087, COSV53095227; called by muse, mutect2, varscan2
- PLD1 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs573013236; called by muse, mutect2, varscan2
- RELB | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 13/318 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1302864766; called by muse, mutect2
- SEC13 | c.241C>T p.R81W (on ENST00000350697 / NM_183352.3; = p.R84W on NM_030673.4) | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762583003, COSV61601520; called by muse, mutect2, varscan2
- SHOX | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM134679, COSV100479363; called by muse, mutect2, varscan2
- SLC37A2 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs34131472; called by muse, mutect2, varscan2
- SLCO4C1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as COSV60519337; called by muse, mutect2
- SLX4IP | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs755366780; called by mutect2, varscan2
- SSC5D | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); catalogued as rs866518503, COSV52700725; called by muse, mutect2, varscan2
- SSTR4 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV54800656; called by muse, mutect2, varscan2
- SVEP1 | c.1400A>G p.D467G | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.197); catalogued as rs746652357; called by muse, mutect2, varscan2
- TEKT4 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as rs782481086, COSV54623336, COSV99726757; called by muse, mutect2, varscan2
- TG | c.7588C>T p.R2530* | Nonsense Mutation (SNP) | VAF 73/297 reads (25%) | catalogued as rs779592637; called by muse, mutect2, varscan2
- TRAV1-1 | c.123C>G p.Y41* | Nonsense Mutation (SNP) | VAF 27/195 reads (14%) | catalogued as rs1463069746; called by muse, mutect2, varscan2
- TUBGCP2 | c.1834G>A p.G612S | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs374883403; called by muse, mutect2, varscan2
- UBR1 | c.3328G>C p.E1110Q | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as CM144367; called by muse, mutect2, varscan2
- A2ML1 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- ABCA13 | c.1655A>C p.D552A | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- ABCG4 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 124/491 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACIN1 | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AMACR | c.107G>C p.R36P | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2
- ANO8 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 79/455 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- ARMC4 | c.1386+1G>C p.X462_splice | Splice Site (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- ARSJ | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP8B3 | c.549C>A p.F183L | Missense Mutation (SNP) | VAF 48/226 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- AXIN2 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 155/454 reads (34%) | called by muse, mutect2, varscan2
- CCDC168 | c.15007G>T p.G5003* | Nonsense Mutation (SNP) | VAF 35/343 reads (10%) | called by muse, mutect2, varscan2
- CDH18 | c.2254T>C p.S752P | Missense Mutation (SNP) | VAF 49/418 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CDH18 | c.1694A>T p.Y565F | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.024); called by muse, mutect2
- CDH4 | c.1651G>A p.A551T | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP128 | c.1055G>A p.R352K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- CNTN1 | c.1330C>G p.P444A | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0.173); called by muse, mutect2
- COL25A1 | c.302C>G p.S101C | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CPLX2 | c.49G>T p.G17W | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DENND1C | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- DNAH3 | c.4192A>C p.N1398H | Missense Mutation (SNP) | VAF 70/299 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPP10 | c.774C>G p.D258E | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EEF1AKNMT | c.1838T>G p.L613R (on ENST00000361735 / NM_015935.5; = p.L527R on NM_014955.3) | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERO1B | c.467G>C p.R156T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ERVV-1 | c.484T>G p.L162V | Missense Mutation (SNP) | VAF 60/798 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.364); called by muse, mutect2
- EYS | c.862+4A>G | Splice Region (SNP) | VAF 16/185 reads (9%) | called by muse, mutect2
- FAM153B | c.935T>C p.M312T (on ENST00000253490; = p.M235T on NM_001265615.1) | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- FAT1 | c.11150_11160del p.S3717* | Frame Shift Del (DEL) | VAF 75/548 reads (14%) | called by mutect2, pindel, varscan2
- FILIP1 | c.530G>A p.R177K | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- GPR21 | c.1042C>T p.H348Y | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.129); called by muse, mutect2
- HMCN2 | c.14609G>A p.R4870K | Missense Mutation (SNP) | VAF 29/191 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KIF2A | c.878C>G p.T293S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.364); called by muse, mutect2
- KLKB1 | c.1274G>C p.G425A | Missense Mutation (SNP) | VAF 44/340 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KLLN | c.75dup p.V26Sfs*5 | Frame Shift Ins (INS) | VAF 28/217 reads (13%) | called by mutect2, pindel, varscan2
- LETM2 | c.854C>T p.A285V (on ENST00000379957 / NM_001286819.2; = p.A190V on NM_144652.3) | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.155); called by muse, mutect2
- LMF2 | c.397A>C p.T133P | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- LTN1 | c.1013A>G p.K338R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MAMDC4 | c.439C>A p.H147N | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MYO1G | c.1184A>C p.D395A | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NACAD | c.3229G>T p.E1077* | Nonsense Mutation (SNP) | VAF 102/458 reads (22%) | called by muse, mutect2, varscan2
- NELL1 | c.2374A>G p.K792E | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- NINL | c.3114G>T p.Q1038H | Missense Mutation (SNP) | VAF 126/309 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUDT9 | c.72C>G p.I24M | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10G7 | c.378T>G p.S126R | Missense Mutation (SNP) | VAF 28/976 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2
- OR1N1 | c.530G>C p.C177S | Missense Mutation (SNP) | VAF 99/435 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- OTULINL | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- PARVG | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- PDE10A | c.508A>C p.K170Q | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2
- PRAMEF20 | c.1066T>G p.L356V | Missense Mutation (SNP) | VAF 87/591 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RADIL | c.3047C>G p.A1016G | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- RYR2 | c.10394T>C p.L3465P | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SACS | c.10762A>C p.N3588H | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SALL4 | c.1174G>T p.G392W | Missense Mutation (SNP) | VAF 211/538 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAMD14 | c.845C>G p.S282C (on ENST00000330175 / NM_001257359.2; = p.S310C on NM_174920.4) | Missense Mutation (SNP) | VAF 98/347 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- SRPRA | c.387G>C p.K129N | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.229); called by muse, mutect2
- SYNE1 | c.21932A>T p.K7311M (on ENST00000367255 / NM_182961.4; = p.K7240M on NM_033071.3) | Missense Mutation (SNP) | VAF 65/767 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- THBS2 | c.2899T>G p.L967V | Missense Mutation (SNP) | VAF 56/431 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRIM77 | c.143C>G p.T48S | Missense Mutation (SNP) | VAF 39/322 reads (12%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TTC34 | c.1887_1888insT p.A630Cfs*63 | Frame Shift Ins (INS) | VAF 22/154 reads (14%) | called by mutect2, pindel, varscan2
- WNK4 | c.1460A>T p.E487V | Missense Mutation (SNP) | VAF 52/363 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- ZNF410 | c.299_316del p.F100_E105del | In Frame Del (DEL) | VAF 24/129 reads (19%) | called by mutect2, pindel, varscan2
- ADAMTSL1 | c.1503C>A p.V501= | Silent (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- ADGRB3 | c.2661T>G p.L887= | Silent (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
- ANKRD11 | c.4845C>T p.S1615= | Silent (SNP) | VAF 50/463 reads (11%) | catalogued as rs140467207; called by muse, mutect2, varscan2
- BBS7 | c.984A>G p.P328= | Silent (SNP) | VAF 17/147 reads (12%) | called by muse, mutect2, varscan2
- CELF5 | c.702G>A p.T234= | Silent (SNP) | VAF 25/212 reads (12%) | catalogued as rs779034828; called by muse, mutect2, varscan2
- COG3 | c.2259A>C p.A753= | Silent (SNP) | VAF 23/108 reads (21%) | called by muse, mutect2, varscan2
- CTNND2 | c.3117G>A p.S1039= | Silent (SNP) | VAF 22/236 reads (9%) | catalogued as rs531016201, COSV58909404; called by muse, mutect2
- DAB2IP | c.381G>A p.R127= (on ENST00000408936; = p.R99= on NM_032552.3) | Silent (SNP) | VAF 51/250 reads (20%) | called by muse, mutect2, varscan2
- DAPK2 | c.213C>T p.I71= | Silent (SNP) | VAF 73/458 reads (16%) | catalogued as rs375258891; called by muse, mutect2, varscan2
- ENOX1 | c.666G>A p.R222= | Silent (SNP) | VAF 66/411 reads (16%) | catalogued as rs763088572; called by muse, mutect2, varscan2
- FAM228B | c.630C>T p.N210= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as rs1477420862, COSV68179201; called by muse, mutect2, varscan2
- FAT3 | c.10839C>T p.S3613= | Silent (SNP) | VAF 35/493 reads (7%) | catalogued as rs745585787, COSV53106067; called by muse, mutect2
- FLG2 | c.5220C>A p.V1740= | Silent (SNP) | VAF 84/665 reads (13%) | called by mutect2, varscan2
- GREB1 | c.1479G>A p.A493= | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as rs759449629; called by muse, mutect2, varscan2
- INPP4B | c.1503C>T p.P501= | Silent (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- IQGAP1 | c.2754A>G p.G918= | Silent (SNP) | VAF 43/263 reads (16%) | called by muse, mutect2, varscan2
- ITIH6 | c.3504C>T p.G1168= | Silent (SNP) | VAF 19/197 reads (10%) | catalogued as rs1183873201; called by muse, mutect2
- KCNA4 | c.276G>A p.K92= | Silent (SNP) | VAF 50/361 reads (14%) | catalogued as COSV60251031; called by muse, mutect2, varscan2
- KCNA5 | c.1449C>T p.Y483= | Silent (SNP) | VAF 64/413 reads (15%) | catalogued as rs766020985, COSV99364252; called by muse, mutect2, varscan2
- LDHA | c.33T>C p.N11= | Silent (SNP) | VAF 52/155 reads (34%) | called by muse, mutect2, varscan2
- LRRC4B | c.693G>C p.L231= | Silent (SNP) | VAF 41/288 reads (14%) | called by muse, mutect2, varscan2
- MAGEC2 | c.354C>T p.S118= | Silent (SNP) | VAF 10/168 reads (6%) | called by muse, mutect2
- MEN1 | c.297C>T p.G99= | Silent (SNP) | VAF 101/284 reads (36%) | called by muse, mutect2, varscan2
- MOS | c.840G>A p.S280= | Silent (SNP) | VAF 10/234 reads (4%) | called by muse, mutect2
- MYH6 | c.1785G>T p.L595= | Silent (SNP) | VAF 82/586 reads (14%) | called by mutect2, varscan2
- NRXN1 | c.321G>A p.T107= | Silent (SNP) | VAF 50/176 reads (28%) | catalogued as rs776382029, COSV101276264; called by muse, mutect2, varscan2
- OR4B1 | c.558C>A p.A186= | Silent (SNP) | VAF 60/425 reads (14%) | catalogued as COSV58882624; called by mutect2, varscan2
- PCDH7 | c.732C>T p.F244= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- PCDHB4 | c.1977G>A p.V659= | Silent (SNP) | VAF 123/731 reads (17%) | catalogued as rs1554274684; called by muse, mutect2, varscan2
- PCDHGB5 | c.1401C>T p.I467= | Silent (SNP) | VAF 59/389 reads (15%) | catalogued as rs749580875, COSV53918013; called by muse, mutect2, varscan2
- PCDHGB6 | c.1623G>A p.T541= | Silent (SNP) | VAF 90/641 reads (14%) | catalogued as COSV53893983; called by muse, mutect2, varscan2
- PEG3 | c.3858C>G p.V1286= | Silent (SNP) | VAF 11/295 reads (4%) | called by muse, mutect2
- PSD | c.1797C>A p.V599= | Silent (SNP) | VAF 32/318 reads (10%) | called by muse, mutect2
- RASA3 | c.90G>A p.P30= | Silent (SNP) | VAF 110/289 reads (38%) | catalogued as rs562261149, COSV100481289; called by muse, mutect2, varscan2
- RBMXL2 | c.750C>T p.D250= | Silent (SNP) | VAF 42/299 reads (14%) | catalogued as rs757089818; called by muse, mutect2, varscan2
- RIMS2 | c.1342T>C p.L448= (on ENST00000666250 / NM_001348490.2; = p.L256= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 9/248 reads (4%) | catalogued as COSV51669105, COSV51676746; called by muse, mutect2
- SCN10A | c.4917C>T p.D1639= | Silent (SNP) | VAF 67/520 reads (13%) | catalogued as rs142804903; called by muse, mutect2, varscan2
- SLC25A2 | c.117G>A p.T39= | Silent (SNP) | VAF 36/308 reads (12%) | called by muse, mutect2
- SLC47A2 | c.690C>T p.N230= | Silent (SNP) | VAF 55/245 reads (22%) | catalogued as rs371191511; called by muse, mutect2, varscan2
- SLC7A1 | c.255C>T p.G85= | Silent (SNP) | VAF 76/444 reads (17%) | called by muse, mutect2, varscan2
- SOD3 | c.333C>T p.R111= | Silent (SNP) | VAF 46/166 reads (28%) | catalogued as rs1417985999, COSV101181133; called by muse, mutect2, varscan2
- SOX7 | c.273G>A p.K91= | Silent (SNP) | VAF 34/165 reads (21%) | catalogued as COSV58730223; called by muse, mutect2, varscan2
- SPATA2L | c.945G>A p.E315= | Silent (SNP) | VAF 76/264 reads (29%) | called by muse, mutect2, varscan2
- TMEM132D | c.621G>C p.T207= | Silent (SNP) | VAF 61/390 reads (16%) | catalogued as COSV101396847, COSV101398768; called by muse, mutect2, varscan2
- TRPM1 | c.1449C>T p.N483= | Silent (SNP) | VAF 98/571 reads (17%) | catalogued as rs773549701, COSV56633229; called by muse, mutect2, varscan2
- UBE2O | c.3660G>A p.S1220= | Silent (SNP) | VAF 64/197 reads (32%) | catalogued as rs144152682; called by muse, mutect2, varscan2
- VCAN | c.714T>C p.T238= | Silent (SNP) | VAF 22/558 reads (4%) | catalogued as COSV54095802, COSV54096791; called by muse, mutect2
- ZNF536 | c.489C>T p.C163= | Silent (SNP) | VAF 87/302 reads (29%) | catalogued as rs1427014287, COSV62818202; called by muse, mutect2, varscan2
- ZNF586 | c.213G>A p.T71= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as rs1045289802, COSV66972552; called by muse, mutect2, varscan2
- ZW10 | c.1392A>G p.E464= | Silent (SNP) | VAF 69/282 reads (24%) | called by muse, mutect2, varscan2
- ACO1 | c.-40C>T | 5'UTR (SNP) | VAF 9/100 reads (9%) | catalogued as rs1159932499; called by muse, mutect2
- ADAM10 | c.207-9191T>G | Intron (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- AL353753.1 | n.471A>C | RNA (SNP) | VAF 19/131 reads (15%) | called by muse, mutect2, varscan2
- ATG2B | chr14:96276289 G>T | 3'Flank (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2, varscan2
- CAV3 | c.*19C>T | 3'UTR (SNP) | VAF 21/137 reads (15%) | catalogued as rs369648984; called by muse, mutect2, varscan2
- CDK11A | chr1:1701668 G>A | 3'Flank (SNP) | VAF 44/151 reads (29%) | called by muse, mutect2, varscan2
- CNTN6 | c.-385C>G | 5'UTR (SNP) | VAF 32/115 reads (28%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53010173 C>G | 5'Flank (SNP) | VAF 28/235 reads (12%) | called by muse, mutect2, varscan2
- EYS | c.1767-8430G>A | Intron (SNP) | VAF 51/257 reads (20%) | called by muse, mutect2, varscan2
- FAM183BP | n.460G>A | RNA (SNP) | VAF 42/194 reads (22%) | called by muse, mutect2, varscan2
- FAM205BP | n.70G>A | RNA (SNP) | VAF 40/158 reads (25%) | catalogued as rs544077348; called by muse, mutect2, varscan2
- FOXI2 | chr10:127736601 G>A | 5'Flank (SNP) | VAF 46/165 reads (28%) | called by muse, mutect2, varscan2
- FRMD8P1 | n.935G>T | RNA (SNP) | VAF 78/368 reads (21%) | called by muse, mutect2, varscan2
- GTF2IRD2B | c.239-19G>A | Intron (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2
- KCNQ4 | c.*49G>A | 3'UTR (SNP) | VAF 39/327 reads (12%) | called by muse, mutect2, varscan2
- KCTD19 | c.301-1000G>A | Intron (SNP) | VAF 13/151 reads (9%) | catalogued as rs530450071; called by muse, mutect2
- KLRC2 | c.585-53T>C | Intron (SNP) | VAF 49/335 reads (15%) | called by muse, mutect2, varscan2
- LPA | c.-44T>A | 5'UTR (SNP) | VAF 60/136 reads (44%) | called by muse, mutect2
- LRRC37BP1 | n.1012C>T | RNA (SNP) | VAF 85/313 reads (27%) | catalogued as rs758280974; called by muse, mutect2, varscan2
- MASP1 | c.1304-4940A>C | Intron (SNP) | VAF 54/426 reads (13%) | called by muse, mutect2, varscan2
- MDM2 | c.174+990C>A | Intron (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- METTL26 | chr16:638466 G>C | 5'Flank (SNP) | VAF 74/393 reads (19%) | called by muse, mutect2, varscan2
- MRPL4 | c.124+11C>T | Intron (SNP) | VAF 50/200 reads (25%) | catalogued as rs1276956685; called by muse, mutect2, varscan2
- MYO1B | c.1186-35G>C | Intron (SNP) | VAF 50/322 reads (16%) | called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442536 C>A | 3'Flank (SNP) | VAF 44/255 reads (17%) | catalogued as rs773631311; called by muse, mutect2, varscan2
- PIGS | c.1081-242C>T | Intron (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- RLN1 | c.211+171C>T | Intron (SNP) | VAF 22/154 reads (14%) | called by muse, mutect2, varscan2
- SCOC | chr4:140369316 C>A | 5'Flank (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- SPATA31D5P | n.598A>C | RNA (SNP) | VAF 78/595 reads (13%) | called by muse, mutect2, varscan2
- TENM3 | c.511+102112G>A | Intron (SNP) | VAF 10/40 reads (25%) | called by muse, varscan2
- TMEM135 | c.*2628G>A | 3'UTR (SNP) | VAF 37/339 reads (11%) | catalogued as rs1029863834; called by muse, mutect2, varscan2
- TRIM74 | chr7:72969926 G>C | 5'Flank (SNP) | VAF 40/410 reads (10%) | called by muse, mutect2
- WDR37 | c.138+2149C>T | Intron (SNP) | VAF 17/146 reads (12%) | catalogued as rs762176219; called by muse, mutect2, varscan2
- XIAP | c.*4303A>G | 3'UTR (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
